Gene-level copy-number profile of tumor specimen TCGA-CQ-5332-01A from TCGA case TCGA-CQ-5332, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 87.7 years (32,032 days).
Specimen TCGA-CQ-5332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.85240fd3-5de6-46b9-a20d-310e2ce951e3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-5332-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6ee3c566-add5-43c1-9e6e-7d26e0a01abc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 641; copy number 2: 13,510; copy number 3: 14,860; copy number 4: 23,821; copy number 5: 2,048; copy number 6: 1,381; copy number 7: 2,935; copy number 8: 18; copy number 9: 12; copy number 10: 84; copy number 11: 26; copy number 12: 110; copy number 14: 4; copy number 15: 104; copy number 16: 128; copy number 18: 10; copy number 19: 49; copy number 21: 34; copy number 22: 12; copy number 24: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-5332-01A-01D-1682-01): tumor purity 0.64, ploidy 3.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:77,421,619–77,561,044, 3 genes (within-gene range 0–2): AC124254.2, AC124254.1, BDP1P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 597 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:163,152,251–164,843,679, 11 genes, copy number 15: RPL7P61, RNU6-627P, FIGN, AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F.
- chr2:164,858,432–164,955,525, 3 genes, copy number 15: RNA5SP110, RNA5SP111, SLC38A11.
- chr2:171,922,448–190,569,776, 292 genes, copy number 15–21 (broad region; genes not listed).
- chr2:190,646,746–192,194,933, 24 genes, copy number 24 (within-gene range 4–24): NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, NABP1-OT1, AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1, TMEFF2.
- chr3:150,761,937–151,657,966, 21 genes, copy number 11 (within-gene range 7–11): SIAH2-AS1, CLRN1-AS1, MINDY4B, AC020636.2, AC020636.1, CLRN1, AC108726.1, MED12L, RNA5SP145, GPR171, P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066.
- chr4:42,110,853–42,268,110, 2 genes, copy number 11 (within-gene range 7–11): BEND4, AC111006.1.
- chr6:46,438,310–47,042,350, 13 genes, copy number 11–18: AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1.
- chr6:49,430,360–61,681,049, 158 genes, copy number 10–22 (broad region; genes not listed).
- chr6:61,870,097–61,893,882, 1 gene, copy number 10: AL355347.1.
- chr6:63,440,766–63,779,336, 9 genes, copy number 9: AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 9: AL354719.1, SCAT8, GCNT1P4.
- chr8:109,362,461–118,111,826, 60 genes, copy number 10–14 (within-gene range 7–14): PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1.

Autosomal genes at a single copy (total copy number 1): 104. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
